Surgical pathology report (de-identified scan), TCGA case TCGA-CW-5580, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-CW-5580-01A (Primary Tumor).

Patient Identifier: [REDACTED]

[REDACTED] Surgical Pathology

TISSUE DESCRIPTION:

Right kidney (14.5 x 7.5 x 6.5 cm) with 8.5 cm right ureter

DIAGNOSIS:

Kidney, right, nephrectomy: Grade 3 (of 4) renal cell carcinoma, clear cell type, forms a 8 x 8 x 6 cm mass located in the superior mid kidney. The tumor exhibits extension into perinephric fat. The renal vein is free of involvement. Coagulative tumor necrosis is present. The surgical margins are negative. No renal hilar lymph nodes are identified. No adrenal gland is present.

Source: NCI Genomic Data Commons file fe7a7a79-8014-4b57-9e1b-39e2f0615f9e (TCGA-CW-5580.2EB52034-FD54-417A-8073-3ED405E723A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).